Gene-level copy-number profile of tumor specimen C3N-02252-74 from CPTAC case C3N-02252, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G3.
Specimen C3N-02252-74: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4f7b7ba0-31a1-4ed2-8be0-548fe28e44e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02252-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/4d8dc244-d086-456a-98a9-00f7aa447eaa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 192; copy number 2: 16,114; copy number 3: 4,805; copy number 4: 29,286; copy number 5: 1,826; copy number 6: 4,275; copy number 7: 240; copy number 8: 72; copy number 9: 410; copy number 10: 147; copy number 11: 291; copy number 12: 291; copy number 13: 415; copy number 37: 7.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:49,502,145–49,589,529, 11 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–2): AC114786.3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,561 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–144,305,180, 36 genes, copy number 10–37: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1.
- chr3:138,261,437–185,153,060, 739 genes, copy number 11–13 (within-gene range 2–13) (broad region; genes not listed).
- chr3:185,914,558–198,123,232, 276 genes, copy number 9 (broad region; genes not listed).
- chr9:12,134–113,754, 9 genes, copy number 9: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388.
- chr18:45,034–5,385,330, 114 genes, copy number 9–11 (broad region; genes not listed).
- chr19:34,533,427–40,390,181, 327 genes, copy number 10–13 (broad region; genes not listed).
- chr19:58,059,239–58,605,223, 60 genes, copy number 9: ZNF135, RN7SL526P, ZSCAN18, ZNF329, AC008751.1, AC008751.3, AC008751.2, ZNF274, RPS15AP36, AC020915.3, ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10, ZNF497, AC012313.2, AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.

Autosomal genes at a single copy (total copy number 1): 192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
